Surgical pathology report (de-identified scan), TCGA case TCGA-39-5030, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site MSKCC, specimen TCGA-39-5030-01A (Primary Tumor).

[page 1 of 6]
TCGA-39-5030

TINIMO. Positive PET and positive PET in node

Specimens Submitted:

- 1: SP: Right level four lymph node
- 2: SP: Level seven lymph node
- 3: SP: Left level 10 lymph node
- 4: SP: Left level nine lymph node
- 5: SP: Level 7 lymph node
- 6: SP: Left level 11 interlobar lymph node
- 7: SP: Left level 10 lymph node
- 8: SP: Level 5 lymph node
- 9: SP: Left lower lobe of lung

DIAGNOSIS:

1. LYMPH NODE, RIGHT LEVEL FOUR; EXCISION:
- FRAGMENTS OF BENIGN LYMPH NODES.
2. LYMPH NODE, LEVEL SEVEN; EXCISION:
- FRAGMENTS OF BENIGN LYMPH NODES.
3. LYMPH NODE, LEFT LEVEL 10; EXCISION:
- ONE OUT OF TWO LYMPH NODES POSITIVE FOR METASTATIC SQUAMOUS CELL CARCINOMA (1/2).
4. LYMPH NODE, LEFT LEVEL NINE; EXCISION:
- ONE OUT OF TWO LYMPH NODES POSITIVE FOR METASTATIC SQUAMOUS CELL CARCINOMA (1/2).
5. LYMPH NODE, LEVEL 7; EXCISION:
- POSITIVE FOR METASTATIC CARCINOMA.
6. LYMPH NODE, LEFT LEVEL 11, INTERLOBAR; EXCISION:
- ONE OUT OF TWO LYMPH NODES ARE POSITIVE FOR METASTATIC CARCINOMA (1/2).

** Continued on next page **

[page 2 of 6]
7. LYMPH NODE, LEFT LEVEL 10; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
8. LYMPH NODE, LEVEL 5; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
9. LUNG, LEFT LOWER LOBE; LOBECTOMY:
- SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED, OF LEFT LOWER LOBE.
- THE TUMOR MEASURES 3.8 X 1.8 X 1.6 CM.
- VASCULAR INVASION IS PRESENT.
- NO PERINEURAL INVASION IS IDENTIFIED.
- THE BRONCHIAL MARGIN IS FREE OF TUMOR.
- THE TUMOR EXTENDS SUBPLEURALLY BUT NOT TO THE PLEURAL SURFACE.
- NO IN SITU CARCINOMA IS IDENTIFIED.
- THE NON-NEOPLASTIC LUNG SHOWS THE FOLLOWING ABNORMALITIES: FOCAL
ATELECTASIS, EMPHYSEMATOUS CHANGES, CHRONIC BRONCHITIS, RESPIRATORY
BRONCHIOLITIS, SCAR.
- THE LYMPH NODE STATUS IS AS FOLLOW (EXPRESSED AS THE NUMBER OF METASTATIC
NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED): PERIBRONCHIAL 4/4.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

1). The specimen is received fresh for frozen section consultation, labeled
"Right level 4 lymph node" and consists of four pieces of tan-pink lymphoid
tissue measuring 1.0 x 1.0 x 0.2 cm in aggregate. Entirely submitted for
frozen section.

Summary of sections:
FSC -- frozen section control

2). The specimen is received fresh for frozen section consultation, labeled
"Level 7 lymph node" and consists of multiple pieces of anthracotic lymphoid
tissue measuring 1.0 x 0.9 x 0.2 cm in aggregate. Entirely submitted for
frozen section.

Summary of sections:
FSC -- frozen section control

3). The specimen is received fresh for frozen section consultation, labeled
"Left level 10 lymph node" and consists of two lymph nodes measuring 2.4 x

** Continued on next page **

[page 3 of 6]
----- Page 3 of 6
1.5 x 1.2 cm, and 1.2 x 0.6 x 0.4 cm. Representative sections are submitted for frozen section consultation and to TPS. The remaining tissue is entirely submitted for permanent section.

Summary section
PSC-frozen section control
R - remaining tissue

4). The specimen is received in formalin, labeled "Left level 9 node" and consists of two anthracotic lymph nodes measuring 1.3 and 2.2 cm in greatest dimension. The lymph nodes are entirely submitted.

Summary of sections:
SLN-trisected lymph node
BLN-bisected lymph node

5). The specimen is received in formalin, labeled "Level 7 lymph node" and consists of a matted cluster of anthracotic lymph nodes measuring 3.2 x 1.5 x 0.4 cm, with approximately 9 lymphoid profiles identified ranging in size from 0.2 to 0.7 cm in greatest dimension. The specimen is submitted entirely.

Summary of sections:
U-undesignated

6). The specimen is received in formalin, labeled "Left level 11 interlobar lymph node" and two anthracotic lymph nodes measuring 0.6 and 1.3 cm in greatest dimension. The lymph nodes are entirely submitted.

Summary of sections:
BLN1 -- bisected lymph node number one
BLN2 -- bisected lymph node number two

7). The specimen is received in formalin, labeled "Left level 10 lymph node" and consists of an anthracotic lymph node measuring 1.1 cm in greatest dimension which is bisected and submitted entirely.

Summary of sections:
BLN bisected lymph node

8). The specimen is received in formalin, labeled "Level 5 lymph node" and consists of an anthracotic lymph node measuring 0.7 cm in greatest

** Continued on next page **

[page 4 of 6]
dimension, which is submitted whole.

Summary of sections:

U-undesignated

9.) The specimen is received fresh, labeled "left lower lobe of lung". It consists of a 15 x 9 x 3.5 cm lung lobe with attached bronchus and blood vessels straddled by multiple staple lines, which weighs 103.5 gm following fixation. The attached bronchus measures 1 cm in length. The pleural surface is smooth and glistening with a puckered area over a subpleural tumor. The specimen is received partially opened. The pleural surface is inked black. Serial sectioning reveals a 3.8 x 1.8 x 1.6 cm white-tan, stellate tumor. The tumor has irregular borders. The tumor is situated in the peripheral lung parenchyma, located 6.5 cm from the bronchial margin and 3.5 cm from the closest staple line. The tumor grossly does not involve the bronchus. The bronchial mucosa is smooth and glistening. Peribronchial anthracotic lymph nodes are identified and submitted. The uninvolved lung parenchyma shows congestion. Representative sections are submitted. TPS is submitted and photographs are taken.

Summary of sections:

BM -- bronchial margin.

VM -- vascular margin.

SM -- staple margin.

T -- tumor

RA - random lung parenchyma at least 3 cm away from main tumor

RC - random lung parenchyma close to tumor (within 3 cm of main tumor)

LN -- lymph nodes

Summary of Sections:

Part 1: SP: Right level four lymph node

Block	Sect.	Site	PCs
1	fsc		1

Part 2: SP: Level seven lymph node

Block	Sect.	Site	PCs
1	fsc		1

Part 3: SP: Left level 10 lymph node

Block	Sect.	Site	PCs
1	fsc		1
1	r		1

Part 4: SP: Left level nine lymph node

** Continued on next page **

[page 5 of 6]
Block	Sect. Site	PCs
2	bln	2
1	sln	1

Part 5: SP: Level 7 lymph node

Block	Sect. Site	PCs
1	u	1

Part 6: SP: Left level 11 interlobar lymph node

Block	Sect. Site	PCs
1	bln1	1
1	bln2	1

Part 7: SP: Left level 10 lymph node

Block	Sect. Site	PCs
1	bln	1

Part 8: SP: Level 5 lymph node

Block	Sect. Site	PCs
1	u	1

Part 9: SP: Left lower lobe of lung

Block	Sect. Site	PCs
1	BM	1
1	LN	1
3	RA	3
3	RC	3
1	SH	1
4	T	4
1	VM	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: BENIGN LYMPH NODE
PERMANENT DIAGNOSIS: SAME
- 2) FROZEN SECTION DIAGNOSIS: BENIGN LYMPH NODE
PERMANENT DIAGNOSIS: SAME
- 3) FROZEN SECTION DIAGNOSIS: METASTATIC SQUAMOUS CELL CARCINOMA
PERMANENT DIAGNOSIS: SAME

** Continued on next page **

[page 6 of 6]
**** End of Report ****

Source: NCI Genomic Data Commons file 4b34d901-0aef-43bc-b31a-8d7f77ccc350 (TCGA-39-5030.AE1B3081-2545-4236-94B3-2D474B021363.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).